Surgical pathology report (de-identified scan), TCGA case TCGA-GU-A766, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - UT Southwestern Medical Center at Dallas, specimen TCGA-GU-A766-01A (Primary Tumor).

[page 1 of 4]
**BIOPSY OR SURGICAL SPECIMEN (Order**

Patient Name _____

MRN

Sex

DOB

Status

Provider Status
Reviewed

Entry Date

Component Results

Component

Lab

Patient Name:

Med Rec #

Accession #:

ICD-0-3
Carcinoma, urothelial NOS
8/20/13
c67
Site Bladder NOS
c67.9
path
Bladder neck
c67.5
JUS/3/13

FINAL PATHOLOGICAL DIAGNOSIS

A. Right pelvic lymph node, dissection:

- One lymph node, negative for tumor (0/1)

B. Right distal ureter, resection:

- Fragment of ureter
- No dysplasia or carcinoma identified
- Frozen section diagnosis confirmed

C. Left distal ureter margin, resection

- Fragment of ureter
- No dysplasia or carcinoma identified
- Frozen section diagnosis confirmed

D. Prostate, bladder, cystoprostatectomy:

- Invasive high grade urothelial carcinoma infiltrating into muscularis propria (3.7 cm)
- pT2a, N0MX (see attached CAP template)
- Seven lymph nodes, negative for tumor (0/7)
- Acute and chronic cystitis giant cell reaction consistent with previous resection site

E. Left obturator lymph nodes, dissection:

- Five lymph nodes, negative for tumor (0/5)

F. Left pelvic lymph nodes, dissection:

- Two lymph nodes, negative for tumor (0/2)

G. Right pelvic lymph node #2, dissection:

- One lymph node, negative for tumor (0/1)
- Frozen section diagnosis confirmed

H. Right obturator lymph node, dissection:

- Three lymph nodes, negative for tumor (0/3)

Criteria	lw 8/5/13	Yes	No
HPA Discrepancy			
Major Malignancy History			
Qual/Synch/Rec Primary Noted			
tequiv/enr initials	MG	Date Prev. visit 8/5/13	

[page 2 of 4]
Specimen: Bladder
Other (specify): prostate and pelvic lymph nodes

Procedure: Radical cystectomy

Tumor Site: Bladder neck and prostatic urethra

Tumor Size: Greatest dimension: 3.7 cm
Additional dimensions: 3.0 x 0.8 cm

Histologic Type: Urothelial (transitional cell) carcinoma

Associated Epithelial Lesions: None identified

Histologic Grade: High-grade

Tumor Configuration: Flat
Ulcerated

Microscopic Tumor Extension: None identified

Margins: Margins uninvolved by invasive carcinoma

Lymph-Vascular Invasion: Not identified

Pathologic Staging (pTNM):
Primary Tumor (pT): pT2a: Tumor invades superficial muscularis
propria (inner half)

Regional Lymph Nodes (pN): pN0: No lymph node metastasis
Specify number examined: 19
Number involved: 0

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: Cystitis cystica glandularis
Inflammation, degenerative changes

Ancillary Studies: Block D6 and D7 can be used for additional studies if
needed.

The above pathology diagnosis incorporates data elements as outlined in the CAP
Cancer Protocols and Checklists which are based on the AJCC/UICC TNM, 7th
edition.

***Electronically Signed Out By
[REDACTED]

CLINICAL HISTORY
Bladder Cancer
Cystectomy and ureteroileal conduit

SPECIMEN(S) RECEIVED
A: Right pelvic lymph node
B: Right distal ureter
C: Left distal ureteral margin
D: Uruncus, prostate, bladder

[page 3 of 4]
E: Left obturator lymph nodes
F: Left pelvic lymph nodes
G: Right pelvic lymph node #2
H: Right obturator lymph nodes

GROSS DESCRIPTION

Specimen A is received in formalin labeled with the patient's name and "right pelvic lymph nodes" and consists of an aggregate of yellow adipose tissue measuring 4.0 x 3.0 x 1.0 cm. A single lymph node is identified measuring 0.8 cm in greatest dimension.

Section key:

A1 one lymph node bisected

A2 additional adipose tissue submitted for possible microscopic lymph node

Specimen B is received fresh for frozen section labeled with the patient's name and "right distal ureter" and consists of a segment of ureter measuring 0.8 cm in length x 0.5 cm in diameter. The specimen is completely submitted for frozen section as B1.

Specimen C is received fresh for frozen section labeled with the patient's name and "left distal ureter" and consists of a segment of ureter measuring 0.3 cm in length x 0.5 cm in diameter. The specimen is completely submitted for frozen section as C1.

Specimen D:

Type of specimen: Urinary bladder, ureter stumps, prostate, seminal vesicles
The patient's name and case number on the specimen container match the accompanying paperwork and cassettes.

Procedure: Radical cystoprostatectomy

Fixative: Received fresh, tissue is taken for research and later submitted in formalin

Dimensions: Bladder SI 6.0 cm, right to left 5.5 cm, anterior to posterior 3.5 cm, right ureter stumps 4.5 x 0.4 cm, left ureter stumps 4.0 x 0.4 cm, prostate base 2.0 cm, apex 4.5 cm, left to right 4.2 cm, anterior to posterior 3.3 cm

Description of findings:

Tumor: The mass is dark dusky red to gray-tan and is located in the bladder neck. It extends radially to involve both ureter orifices. The mass measures approximately 3.7 x 3.0 cm. Sectioning involves possible invasion into the wall, however, no invasion through the wall is identified. The surrounding mucosa including the posterior wall is dusk, red and edematous. The mucosa at the dome is flattened and thin. Sectioning through the surrounding adipose tissue reveals an elongated, fibrous area possibly representing urachus measuring 7.5 cm in length x 0.7 cm in diameter. Multiple lymph nodes are also identified ranging from 0.6 up to 2.7 cm in greatest dimension. The majority of the lymph nodes are grossly positive.

Uninvolved mucosa: (polyps, ulceration, erythema)

Prostate: The prostate urethra is dark, red-gray and roughened with possible involvement by the mass within the bladder. The prostate parenchyma is firm, pale tan to white with a vaguely nodular appearance.

Ink code: Posterior bladder=black, anterior bladder=green, right prostate=orange, left prostate=blue, anterior prostate=green, posterior prostate=black

Section key:

D1 urethral margin

D2 and D3 one complete cross section extending from bladder neck to prostate apex split

D4 longitudinal cross section of right ureter extending to bladder mucosa

D5 longitudinal cross section of left ureter extending to bladder mucosa

D6-D9 representative sections of mass

[page 4 of 4]
D10 section from posterior wall with edema
D11 uninvolved anterior wall
D12 dome
D13 possible urachus
D14 apex right prostate
D15-D17 random sections proceeding from apex to base right prostate
D18 apex left prostate
D19-D21 random sections from apex to base left prostate
D22 distal sections of vas deferens with right vas deferens marked with ink
D23 representative section of largest grossly positive lymph node
D24 one lymph node trisected
D25 two matted lymph nodes bisected
D26 one lymph node bisected
D27 one lymph node bisected
D28 two single lymph nodes

Specimen E is received in formalin labeled with the patient's name and "left obturator lymph nodes" and consists of an aggregate of yellow adipose tissue measuring 6.0 x 3.8 x 2.5 cm. Four lymph nodes are identified ranging from 0.3 up to 4.0 cm in greatest dimension.

Section key:

E1-E4 largest lymph node sectioned

Specimen F is received in formalin labeled with the patient's name and "left pelvic lymph nodes" and consists of an aggregate of yellow adipose tissue measuring 4.5 x 4.5 x 2.0 cm. Two lymph nodes are identified measuring 2.0 cm and 2.7 cm in greatest dimension.

Section key:

F1 and F2 larger lymph node bisected

F3 smaller lymph node bisected

Specimen G is received fresh for frozen section labeled with the patient's name and "right pelvic lymph nodes #2" and consists of an irregular fragment of pale tan and yellow fibrofatty soft tissue measuring 2.5 x 1.0 x 0.8 cm. The specimen is completely submitted for frozen section as G1.

Specimen H is received in formalin labeled with the patient's name and "right obturator lymph nodes" and consists of an aggregate of yellow adipose tissue measuring 5.2 x 3.5 x 2.6 cm. Two lymph nodes are identified measuring 3.5 cm and 2.0 cm. The smaller lymph node is fragmented. The lymph nodes are completely submitted.

MICROSCOPIC DESCRIPTION

The stain quality is acceptable.

The microscopic findings are reflected in the diagnoses rendered.

INTRAOPERATIVE CONSULT DIAGNOSIS

Time in: Time out:
B1-FS, Right distal ureter: "Negative for carcinoma"

Time in: Time out:
C1-FS, Left distal ureteral margin: "Negative for carcinoma"

Time in: Time out:
G1-FS, Right pelvic lymph node #2: "Negative for metastatic carcinoma"

Source: NCI Genomic Data Commons file 34ce7143-c2e3-4d50-b120-d317d01faa5e (TCGA-GU-A766.295B55E8-4220-4342-96E3-C4A8065B3D58.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).